Somatic mutation profile of tumor specimen MP2PRT-PAVKLJ-TMP1-A (aliquot MP2PRT-PAVKLJ-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAVKLJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,493 days).
Specimen MP2PRT-PAVKLJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 314e6d3c-423b-4caa-b87a-b2da78785b8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVKLJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVKLJ-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86413644-df6a-4ed8-83b0-ddf853fa2d9d

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 60/300 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RNF145 | c.1852C>T p.P618S (on ENST00000424310 / NM_001199383.2; = p.P646S on NM_144726.2) | Missense Mutation (SNP) | VAF 62/334 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs761761937; called by muse, mutect2, varscan2
- SPATA19 | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 116/363 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as rs748084811, COSV54484428; called by muse, mutect2, varscan2
- FAM155B | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 136/682 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.287); called by mutect2, varscan2
- FAM90A1 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 20/498 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.385); called by muse, mutect2
- ARFGEF1 | c.3129A>T p.S1043= | Silent (SNP) | VAF 7/119 reads (6%) | called by muse, mutect2
